Gene-level copy-number profile of tumor specimen TCGA-A6-6649-01A from TCGA case TCGA-A6-6649, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 66.4 years (24,237 days).
Specimen TCGA-A6-6649-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.e34cdc5b-0f46-4768-bf40-69cb975b2ce0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A6-6649-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/37b77eeb-e58d-4858-a4d5-154878fa3630

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,397; copy number 3: 36,976; copy number 4: 15,493; copy number 5: 3,645; copy number 6: 623; copy number 7: 532; copy number 8: 77; copy number 10: 10; copy number 11: 29; copy number 12: 21; copy number 17: 3; copy number 18: 4; copy number 20: 8; copy number 25: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A6-6649-01A-11D-1770-01): tumor purity 0.43, ploidy 3.28, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 686 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:68,861,284–114,337,626, 563 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr14:32,271,857–33,804,176, 9 genes, copy number 10 (within-gene range 6–10): KIAA1143P1, AKAP6, AL136298.1, RN7SL660P, MTCO1P2, AL049781.1, NPAS3, AL161851.1, AL161851.2.
- chr14:36,070,427–41,298,734, 68 genes, copy number 10–25 (within-gene range 6–25) (broad region; genes not listed).
- chr14:51,392,128–52,156,179, 24 genes, copy number 8: LINC02310, SETP2, FRMD6-AS2, FRMD6, RNU6-1291P, AL122125.1, FRMD6-AS1, RNA5SP385, RNU6-301P, AL079307.2, OR7E105P, OR7E106P, AL079307.1, OR7E159P, AL079307.3, GNG2, AL358333.2, AL358333.3, AL358333.1, RTRAF, NID2, LINC02319, COX5AP2, AL118557.1.
- chr18:21,981,121–23,026,488, 22 genes, copy number 7: LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
